Somatic mutation profile of tumor specimen TCGA-CV-A6JT-01A (aliquot TCGA-CV-A6JT-01A-11D-A31L-08) from TCGA case TCGA-CV-A6JT, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.2 years (23,806 days).
Specimen TCGA-CV-A6JT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eea29a58-824a-4c7d-8e45-e0bf97b75cce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6JT-10A (Blood Derived Normal), aliquot TCGA-CV-A6JT-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af33769e-87f2-4e7c-b44c-f5db5ac25bc0

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 38, Silent 13, Nonsense Mutation 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TET2 | c.1648C>T p.R550* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | hotspot (GDC flag); catalogued as rs572712965, COSV54395664; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASZ1 | c.1292A>T p.E431V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.265); catalogued as COSV99497692; called by muse, mutect2, varscan2
- AVL9 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100594475; called by muse, mutect2, varscan2
- AVL9 | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100594476; called by muse, mutect2, varscan2
- CBLB | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV99912496; called by muse, mutect2, varscan2
- CCDC150 | c.3265C>T p.P1089S | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs772057889, COSV99776401; called by muse, mutect2, varscan2
- CCR10 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1163586006, COSV99226060; called by muse, mutect2, varscan2
- CHRNB4 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs372392383; called by muse, mutect2, varscan2
- CYP8B1 | c.1299G>C p.W433C | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296000; called by muse, mutect2, varscan2
- DYSF | c.2810C>T p.T937I | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201209494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FES | c.1946G>A p.R649H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs779752765, COSV61000217; called by muse, mutect2, varscan2
- GNA11 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777912441, COSV99312612; called by muse, mutect2, varscan2
- GPM6A | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV54560797, COSV99702277; called by muse, mutect2, varscan2
- HCFC2 | c.1874C>G p.S625* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99982830; called by muse, mutect2, varscan2
- IMPG1 | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs774413589, COSV100885799; called by muse, mutect2, varscan2
- JAM2 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.713); catalogued as COSV100467709; called by muse, mutect2, varscan2
- KLK5 | c.635T>G p.L212R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.247); catalogued as COSV100306796; called by muse, mutect2, varscan2
- MAP3K4 | c.3635C>T p.S1212F | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.259); catalogued as COSV100815097, COSV62335272; called by muse, varscan2
- MYH9 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53386810; called by muse, mutect2, varscan2
- OVOL1 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100256700; called by muse, mutect2, varscan2
- PCDH11X | c.2314G>A p.V772M | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs369246059, COSV100007452; called by muse, mutect2, varscan2
- PLCB3 | c.3377G>A p.R1126H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1268489463, COSV54191407; called by muse, mutect2, varscan2
- QRICH2 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV99428731, COSV99428764; called by muse, mutect2, varscan2
- SAPCD2 | c.697A>G p.K233E | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV101294026; called by muse, mutect2, varscan2
- SKIDA1 | c.1808A>G p.Q603R | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1379052404, COSV101481238; called by muse, mutect2, varscan2
- SLC6A9 | c.130T>G p.F44V | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.003); catalogued as COSV100745975; called by muse, mutect2, varscan2
- SLITRK5 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100280116, COSV100280154; called by muse, mutect2, varscan2
- SPATA5 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as COSV99914539; called by muse, mutect2, varscan2
- SPTBN1 | c.1900C>A p.L634M | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100441586; called by muse, mutect2, varscan2
- SREK1IP1 | c.462A>C p.R154S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV101536160; called by muse, mutect2, varscan2
- ST8SIA5 | c.432G>T p.Q144H | Missense Mutation (SNP) | VAF 25/82 reads (30%) | PolyPhen possibly damaging (0.592); catalogued as COSV100164454; called by muse, mutect2, varscan2
- SUPT3H | c.183G>T p.L61F (on ENST00000371460 / NM_181356.3; = p.L50F on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100175998; called by muse, mutect2, varscan2
- SYNE1 | c.14696G>A p.W4899* (on ENST00000367255 / NM_182961.4; = p.W4828* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV99550986, COSV99572720; called by muse, mutect2, varscan2
- THAP9 | c.1946A>G p.D649G | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs148766490; called by muse, mutect2, varscan2
- TSHZ3 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1460272120, COSV99550444, COSV99550967; called by muse, mutect2, varscan2
- TTN | c.20716C>T p.R6906C (on ENST00000591111; = p.R5979C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | PolyPhen possibly damaging (0.533); catalogued as rs1156609638, COSV59947303, COSV60378018; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VGF | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99972798, COSV99972903; called by muse, mutect2
- YY1AP1 | c.2216C>T p.S739L (on ENST00000295566 / NM_139118.2; = p.S682L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV99803318; called by muse, mutect2, varscan2
- ZMIZ1 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); catalogued as rs138149224, COSV57889612, COSV57894701, COSV57895682; called by muse, mutect2, varscan2
- ZNF628 | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.192); catalogued as rs1274135536, COSV99219731; called by muse, mutect2
- HEPHL1 | c.1889G>A p.G630D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PRAMEF14 | c.790C>A p.L264I | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- AL136295.1 | c.12C>T p.L4= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs1269355856, COSV51662115, COSV99164580; called by muse, mutect2, varscan2
- BORCS5 | c.90G>A p.K30= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV100055741; called by muse, mutect2, varscan2
- CAPN1 | c.2144G>A p.*715= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV54196826; called by muse, mutect2, varscan2
- FCN3 | c.246C>T p.N82= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99585197; called by muse, mutect2, varscan2
- INPP4A | c.777C>A p.P259= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99302268; called by muse, mutect2, varscan2
- MLH3 | c.3312C>T p.S1104= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs149369905; called by muse, mutect2, varscan2
- MMS22L | c.1609C>T p.L537= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99245951; called by muse, mutect2, varscan2
- MYO9B | c.5658G>A p.R1886= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1334599141, COSV101261142, COSV68282030; called by muse, mutect2
- NLRP12 | c.888C>T p.F296= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs538564043, COSV60749158; called by muse, mutect2, varscan2
- NR1H4 | c.378G>A p.A126= (on ENST00000551379 / NM_001206993.2; = p.A116= on NM_005123.4) | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as rs767379406, COSV51849366, COSV51853756; called by muse, mutect2, varscan2
- PPP3R2 | c.72C>A p.G24= | Silent (SNP) | VAF 29/122 reads (24%) | catalogued as COSV100701325; called by muse, mutect2, varscan2
- SEMA3C | c.1782C>T p.P594= | Silent (SNP) | VAF 25/77 reads (32%) | catalogued as COSV99542238; called by muse, mutect2, varscan2
- WIF1 | c.1059C>G p.G353= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as COSV54135274, COSV99682504; called by muse, mutect2, varscan2
